Somatic mutation profile of tumor specimen TCGA-10-0927-01A (aliquot TCGA-10-0927-01A-02W-0420-08) from TCGA case TCGA-10-0927, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 65.7 years (23,982 days).
Specimen TCGA-10-0927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b1f77ff-5783-4234-ad34-d16f3a930655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0927-11A (Solid Tissue Normal), aliquot TCGA-10-0927-11A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4d4515a-0120-4b07-997d-0941fbe1bc13

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 6, Silent 6, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLT8D2 | c.113A>C p.D38A | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62562388; called by mutect2, varscan2
- LRP4 | c.5504dup p.L1836Pfs*24 | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | catalogued as rs745628337; called by mutect2, varscan2
- MADD | c.4927C>T p.R1643W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs770319218, COSV57030249; called by muse, mutect2, varscan2
- OLFML3 | c.795dup p.Y266Lfs*14 | Frame Shift Ins (INS) | VAF 16/109 reads (15%) | catalogued as rs753594963; called by mutect2, varscan2
- OLR1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as COSV58872013; called by mutect2, varscan2
- RAD51AP2 | c.2325T>A p.S775R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV101208359; called by mutect2, varscan2
- TP53 | c.106_118del p.P36Wfs*4 | Frame Shift Del (DEL) | VAF 23/37 reads (62%) | catalogued as COSV53254498; called by mutect2, pindel, varscan2
- UBR5 | c.935A>C p.E312A | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV55292759; called by muse, mutect2, varscan2
- USH2A | c.7924A>T p.I2642L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV56395865; called by mutect2, varscan2
- ZFHX4 | c.6631C>T p.Q2211* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99263899; called by mutect2, varscan2
- CHD6 | c.2361G>A p.L787= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV58559286; called by mutect2, varscan2
- LPAR4 | c.588C>T p.V196= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101425136, COSV70912773, COSV70913244; called by mutect2, varscan2
- LSAMP | c.642T>A p.T214= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100371128; called by mutect2, varscan2
- MAST4 | c.1698G>C p.R566= (on ENST00000403625 / NM_001164664.2; = p.R377= on NM_015183.3) | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV99844553; called by mutect2, varscan2
- PGBD1 | c.2334C>T p.H778= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV52554458; called by mutect2, varscan2
- ZBTB16 | c.195C>T p.R65= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV60095875; called by muse, mutect2, varscan2
